Somatic mutation profile of tumor specimen C3L-01158-01 (aliquot CPT0171630026) from CPTAC case C3L-01158, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 69.1 years (25,247 days).
Specimen C3L-01158-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fbb262a-eabd-4825-ac53-5dc229eca43e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01158-31 (Blood Derived Normal), aliquot CPT0171560002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f9aed60-81b9-465d-9c78-edde1d1fa9f8

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 86/1096 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ATP2B3 | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141644369, COSV54848658; called by muse, mutect2
- CBFA2T3 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1432631709, COSV51924049; called by muse, mutect2
- CLEC11A | c.422A>G p.Q141R | Missense Mutation (SNP) | VAF 17/366 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1163617798; called by muse, mutect2
- COL9A1 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 32/806 reads (4%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.937); catalogued as rs761249181, COSV100295424; called by muse, mutect2
- DNAH5 | c.11528C>T p.S3843L | Missense Mutation (SNP) | VAF 50/800 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs78346432, CM065132, COSV54202507; called by muse, mutect2
- KCNB2 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73048998, COSV73050348; called by muse, mutect2
- NME1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 36/829 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs375550760; called by muse, mutect2
- PDZRN4 | c.2830G>A p.E944K (on ENST00000402685 / NM_001164595.2; = p.E686K on NM_013377.4) | Missense Mutation (SNP) | VAF 20/545 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1350158553, COSV54192586; called by muse, mutect2
- SLC2A11 | c.205C>T p.L69F (on ENST00000345044 / NM_001024938.4; = p.L76F on NM_030807.5) | Missense Mutation (SNP) | VAF 16/351 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs1200541777; called by muse, mutect2
- ZKSCAN2 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 19/598 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF354A | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.146); called by muse, mutect2
- CDH11 | c.426G>A p.P142= | Silent (SNP) | VAF 33/885 reads (4%) | catalogued as rs758854974, COSV51776352; called by muse, mutect2
- POLD1 | c.2874G>C p.L958= | Silent (SNP) | VAF 20/586 reads (3%) | called by muse, mutect2
- TBX19 | c.378G>A p.P126= | Silent (SNP) | VAF 16/628 reads (3%) | called by muse, mutect2
- OR2W5 | n.835C>T | RNA (SNP) | VAF 42/692 reads (6%) | called by muse, mutect2
